CCDI case PBCPEA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3f3b0479-4a60-4d36-baf0-5fc0768ceb30

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Desmoplastic nodular medulloblastoma: ICD-O-3 morphology code: 9471/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 13.0 years (4,765 days).

Biospecimens (3 samples)
- Sample 0DWGJ7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWGJM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DX4F4: Tissue type: Tumor; Specimen type: Solid Tissue.
